Somatic mutation profile of tumor specimen TCGA-C5-A902-01A (aliquot TCGA-C5-A902-01A-11D-A37N-09) from TCGA case TCGA-C5-A902, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 35.5 years (12,959 days).
Specimen TCGA-C5-A902-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59bb5d74-1006-4ffc-84cd-b97f485a6229.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A902-10A (Blood Derived Normal), aliquot TCGA-C5-A902-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b8858ce-480d-484f-b418-689cc7d381ba

The open-access MAF lists 320 somatic variants for this specimen: 224 protein-altering or splice-affecting, 92 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 92, Nonsense Mutation 19, Splice Site 4, Frame Shift Del 4, Splice Region 3, 5'Flank 1, Frame Shift Ins 1, Intron 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTD | c.1279C>T p.H427Y | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397514418, CM086707, COSV100329511; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99537406; called by muse, mutect2, varscan2
- ADAMTSL1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99442053; called by muse, mutect2, varscan2
- ADGRV1 | c.12525C>T p.I4175= | Splice Region (SNP) | VAF 33/103 reads (32%) | catalogued as COSV101315740; called by muse, mutect2, varscan2
- AFF2 | c.2614G>T p.E872* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV53993370, COSV99663202; called by muse, mutect2, varscan2
- AGBL2 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.259); catalogued as COSV100101532; called by muse, mutect2, varscan2
- AGRN | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV101038734; called by muse, mutect2, varscan2
- AHNAK | c.7177C>G p.L2393V | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.417); catalogued as COSV99946819; called by muse, mutect2, varscan2
- AKAP13 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100773497, COSV104419900; called by muse, varscan2
- AKAP13 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100773498; called by muse, varscan2
- AKAP4 | c.2426C>G p.A809G | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV62075842; called by muse, mutect2, varscan2
- ALPK2 | c.3560C>G p.S1187* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100864283; called by muse, mutect2, varscan2
- APOBEC1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV57549254, COSV99981063; called by muse, mutect2, varscan2
- APOBR | c.1462G>A p.E488K (on ENST00000431282; = p.E497K on NM_018690.4) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV100112421; called by muse, mutect2, varscan2
- ARID2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.963); catalogued as COSV100535902, COSV57600725; called by muse, mutect2, varscan2
- ASTE1 | c.2027C>G p.S676C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99393762; called by muse, mutect2, varscan2
- ASTN1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs370485432; called by muse, mutect2, varscan2
- ATIC | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV99377683; called by muse, mutect2, varscan2
- ATOH1 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs139664764; called by muse, mutect2, varscan2
- ATP10A | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs766814441, COSV63516442; called by muse, mutect2, varscan2
- BPI | c.1288G>A p.E430K (on ENST00000262865; = p.E426K on NM_001725.3) | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as COSV99480536; called by muse, mutect2, varscan2
- C10orf90 | c.413C>A p.A138E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52963511; called by muse, mutect2
- C9orf78 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.478); catalogued as COSV100989961; called by muse, varscan2
- C9orf78 | c.744G>C p.L248F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV100989962; called by muse, varscan2
- CAPN2 | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.079); catalogued as COSV54333850; called by muse, mutect2, varscan2
- CCDC130 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55583068, COSV99681186; called by muse, mutect2, varscan2
- CCDC141 | c.4173G>C p.E1391D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV55376721, COSV99836035; called by muse, mutect2, varscan2
- CCDC180 | c.4312C>T p.Q1438* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as COSV100826643; called by muse, mutect2, varscan2
- CCNE2 | c.368G>C p.R123T | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs776621866, COSV100353699; called by muse, mutect2, varscan2
- CD163L1 | c.1085C>A p.S362* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV100549945; called by muse, mutect2, varscan2
- CDC6 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99266539; called by muse, mutect2, varscan2
- CDK12 | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV71001257; called by muse, mutect2, varscan2
- CEP112 | c.2677G>A p.E893K (on ENST00000392769 / NM_001353127.1; = p.E149K on NM_001037325.3) | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV58062958, COSV58067602; called by muse, mutect2, varscan2
- CEP128 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV99824283; called by muse, mutect2, varscan2
- CEP192 | c.4994C>T p.S1665L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV100381008; called by muse, mutect2, varscan2
- CFAP91 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99847024; called by muse, mutect2, varscan2
- CHD6 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100498040, COSV100498622; called by muse, mutect2, varscan2
- CHMP4B | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99459760; called by muse, mutect2, varscan2
- CLK2 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100751848; called by muse, mutect2, varscan2
- CLPX | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV100269423; called by muse, varscan2
- COBLL1 | c.2156C>A p.S719* (on ENST00000392717; = p.S681* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV52065275, COSV52066747, COSV99527707; called by muse, mutect2, varscan2
- CSMD1 | c.6670G>A p.E2224K (on ENST00000520002; = p.E2223K on NM_033225.6) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.988); catalogued as rs754304316, COSV59287313; called by muse, mutect2, varscan2
- CSPG4 | c.3998C>T p.S1333L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs767886749, COSV100413689; called by muse, mutect2, varscan2
- CUBN | c.5771G>C p.G1924A | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.429); catalogued as COSV100912433; called by muse, mutect2, varscan2
- CXCL14 | c.241C>G p.Q81E (on ENST00000337225; = p.Q69E on NM_004887.5) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV100463577; called by muse, mutect2, varscan2
- CXorf56 | c.454G>A p.E152K (on ENST00000536133 / NM_001170570.2; = p.E166K on NM_022101.4) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100233370; called by muse, mutect2, varscan2
- DACH1 | c.2063C>T p.A688V (on ENST00000619232 / NM_001366712.1; = p.A434V on NM_004392.6) | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.642); catalogued as rs867054570, COSV57520025; called by muse, mutect2, varscan2
- DARS2 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1024219171, COSV99508615; called by muse, mutect2, varscan2
- DCAF12L1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV100948215, COSV104427728; called by muse, mutect2, varscan2
- DES | c.1245-2A>G p.X415_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100900373; called by muse, mutect2, varscan2
- DLG4 | c.2092G>A p.E698K (on ENST00000399506 / NM_001321075.3; = p.E741K on NM_001365.4) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV57237270; called by muse, mutect2, varscan2
- DNAH17 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101101961; called by muse, mutect2, varscan2
- DNAH9 | c.3929G>T p.G1310V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV52362274, COSV99305247; called by muse, mutect2, varscan2
- DOCK11 | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353530, COSV99355061; called by muse, mutect2, varscan2
- DOCK11 | c.6112G>A p.E2038K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.205); catalogued as COSV99353532; called by muse, mutect2, varscan2
- DOCK5 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs1239696785, COSV99376643; called by muse, mutect2, varscan2
- DTL | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs1413465321, COSV100877181, COSV65341876; called by muse, mutect2, varscan2
- DTX3L | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99949945; called by muse, mutect2, varscan2
- DTX3L | c.1385G>C p.R462T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV99949947; called by muse, mutect2, varscan2
- EDNRA | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100163321; called by muse, mutect2, varscan2
- EFCAB6 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as COSV99412354; called by muse, mutect2, varscan2
- EHBP1 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV50425940, COSV50445805; called by muse, mutect2, varscan2
- ENAM | c.2859G>C p.R953S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101253019; called by muse, mutect2, varscan2
- EPHA6 | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as COSV101061848, COSV101065804, COSV67575419; called by muse, mutect2, varscan2
- ESF1 | c.791G>T p.R264I | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV52524201; called by muse, mutect2, varscan2
- EXPH5 | c.5905G>C p.D1969H | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99761359; called by muse, mutect2, varscan2
- FABP3 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs1161770591, COSV100703937; called by muse, mutect2, varscan2
- FAM9C | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV100452777; called by muse, mutect2, varscan2
- FBXL4 | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100014020; called by muse, mutect2, varscan2
- FBXO4 | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1208335132, COSV99715095; called by muse, mutect2, varscan2
- FBXO9 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99762380; called by muse, mutect2, varscan2
- FER | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV99812353; called by muse, mutect2, varscan2
- FSCB | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs1262252860, COSV100469162; called by muse, mutect2, varscan2
- FSIP2 | c.17614G>C p.E5872Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV100554778; called by muse, mutect2, varscan2
- GGT5 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs759124656, COSV54068737; called by muse, mutect2, varscan2
- GJA9 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100668076; called by muse, mutect2, varscan2
- GLOD4 | c.749C>T p.P250L (on ENST00000301328 / NM_001366247.1; = p.P235L on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752349761, COSV100022513, COSV100022657; called by muse, mutect2, varscan2
- GOLGA3 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV99202603; called by muse, mutect2, varscan2
- GPR84 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57209818, COSV99909998; called by muse, mutect2, varscan2
- GRK3 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV100151360, COSV60793398; called by muse, mutect2, varscan2
- HCN3 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs370145616; called by muse, varscan2
- HEATR5A | c.2184G>C p.L728F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV101119839; called by muse, varscan2
- HEY1 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as rs138580863; called by muse, mutect2, varscan2
- HIPK1 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100478807; called by muse, mutect2, varscan2
- HNRNPA1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV52937826; called by muse, mutect2, varscan2
- HOXA10 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99385391; called by muse, varscan2
- HROB | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1365585621, COSV99809202; called by muse, mutect2, varscan2
- HSD17B14 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99622721; called by muse, mutect2, varscan2
- HTR1E | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.244); catalogued as COSV100541045, COSV59510408; called by muse, mutect2, varscan2
- HTR4 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV100087699; called by muse, mutect2, varscan2
- HUWE1 | c.9058G>A p.E3020K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99470466, COSV99471613; called by muse, mutect2, varscan2
- ICAM5 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV99320688; called by muse, mutect2, varscan2
- IFT88 | c.1367G>C p.R456T (on ENST00000319980 / NM_001318493.2; = p.R447T on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV100179605; called by muse, mutect2, varscan2
- ISLR2 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV62301841; called by muse, mutect2, varscan2
- JSRP1 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55553958; called by muse, varscan2
- KAT14 | c.1099C>G p.H367D | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV100890057; called by muse, varscan2
- KAT14 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 51/89 reads (57%) | catalogued as COSV100890059; called by muse, mutect2, varscan2
- KAT14 | c.1642C>G p.Q548E | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100890061; called by muse, varscan2
- KAT2B | c.1297G>C p.D433H | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99769128; called by muse, mutect2, varscan2
- KCNMA1 | c.2979C>G p.I993M (on ENST00000286628 / NM_001161352.2; = p.I935M on NM_002247.4) | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.287); catalogued as COSV99696431; called by muse, mutect2, varscan2
- KIAA1210 | c.2312C>G p.S771* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV101274058; called by muse, mutect2, varscan2
- KMT2B | c.6016G>C p.E2006Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV55857905, COSV55864123; called by muse, mutect2, varscan2
- KMT2C | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV51402639, COSV51501644; called by muse, mutect2, varscan2
- LAMA5 | c.6435C>A p.C2145* | Nonsense Mutation (SNP) | VAF 31/118 reads (26%) | catalogued as COSV99439179; called by muse, mutect2, varscan2
- LGI3 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100102981; called by muse, mutect2, varscan2
- LMF1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531415593, COSV51893465; called by muse, mutect2, varscan2
- LMF2 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV99327494; called by muse, mutect2, varscan2
- LMTK3 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1316302615, COSV99540313; called by muse, mutect2, varscan2
- MAP9 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV100250849; called by muse, mutect2, varscan2
- MARVELD3 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.052); catalogued as COSV99194813; called by muse, mutect2, varscan2
- MED12 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV61340982; called by muse, mutect2, varscan2
- MEGF10 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV99174838; called by muse, mutect2, varscan2
- MEP1B | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99328791; called by muse, mutect2, varscan2
- MFAP1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99979810; called by muse, mutect2, varscan2
- MPDZ | c.3320G>A p.R1107K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100056532; called by muse, mutect2, varscan2
- MTIF2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs771628095, COSV99703094; called by muse, mutect2, varscan2
- MUC16 | c.29501C>T p.S9834L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as COSV101199349; called by muse, mutect2, varscan2
- MUC5AC | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.01); catalogued as rs746780691, COSV100650573; called by muse, mutect2, varscan2
- MYH11 | c.5816C>G p.S1939C | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV100258493, COSV55546887; called by muse, mutect2, varscan2
- NADK | c.30G>C p.M10I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV100410762, COSV58274977; called by muse, mutect2, varscan2
- NADSYN1 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV100034617; called by muse, mutect2, varscan2
- NBPF1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101236403, COSV101236875; called by muse, mutect2
- NEURL1 | c.1338C>T p.L446= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as rs1372275527, COSV63915252; called by muse, mutect2
- NF1 | c.2791C>G p.P931A | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs764290369, COSV100646645; called by muse, mutect2, varscan2
- NF1 | c.2927C>A p.T976N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100646646; called by muse, mutect2, varscan2
- NFE2 | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as COSV56456122; called by muse, mutect2, varscan2
- NOS1AP | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100722842, COSV62639774; called by muse, mutect2, varscan2
- NOTUM | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.143); catalogued as COSV101293769; called by muse, mutect2, varscan2
- NUDT13 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.347); catalogued as COSV100624743; called by muse, mutect2, varscan2
- OR2T3 | c.921G>T p.R307S | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV62081740, COSV62082153; called by muse, mutect2, varscan2
- OR2T6 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs760588497, COSV63216564, COSV63216571; called by muse, mutect2, varscan2
- OR4Q3 | c.106T>C p.F36L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV100056933; called by muse, mutect2, varscan2
- OR7G2 | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV100560395; called by muse, mutect2, varscan2
- P3H2 | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs893265403, COSV100077421; called by muse, mutect2, varscan2
- PAK3 | c.760C>T p.R254W (on ENST00000262836 / NM_001324328.2; = p.R239W on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53271848, COSV99458352; called by muse, mutect2, varscan2
- PALD1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1303182708, COSV99698182; called by muse, mutect2, varscan2
- PCDHB1 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as rs140133940, COSV60632314; called by muse, mutect2, varscan2
- PCDHGA10 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99535485; called by muse, mutect2, varscan2
- PCDHGA10 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99535486; called by muse, mutect2, varscan2
- PCDHGA10 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV99535488; called by muse, mutect2, varscan2
- PCNT | c.9061G>A p.E3021K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV100855353; called by muse, mutect2, varscan2
- PEA15 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100470321; called by muse, mutect2, varscan2
- PHACTR4 | c.1393C>T p.L465F (on ENST00000373839 / NM_001350159.2; = p.L475F on NM_023923.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100868426; called by muse, mutect2, varscan2
- PIGG | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99573771; called by muse, mutect2, varscan2
- PIK3R4 | c.3952C>T p.R1318* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as rs765217350, COSV100650148; called by muse, mutect2, varscan2
- PITPNM1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV56873290; called by muse, mutect2, varscan2
- PKD1L2 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100449785; called by muse, mutect2, varscan2
- POLN | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101242492; called by muse, mutect2, varscan2
- POLR3D | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100120050; called by muse, mutect2, varscan2
- POMGNT1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | PolyPhen benign (0.01); catalogued as COSV100915510; called by muse, varscan2
- POU5F1 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99462915; called by muse, mutect2, varscan2
- PPEF2 | c.1705C>T p.H569Y | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs144838414; called by muse, mutect2, varscan2
- PPFIA2 | c.2611C>G p.Q871E | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as COSV100332764, COSV61039789; called by muse, mutect2, varscan2
- PTOV1 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.582); catalogued as rs372052304; called by muse, varscan2
- RALGAPA2 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs755240772, COSV52493252; called by muse, mutect2, varscan2
- RANBP2 | c.2077G>C p.D693H | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99311823; called by muse, mutect2, varscan2
- RELN | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633245; called by muse, mutect2, varscan2
- RNF31 | c.2609-1G>A p.X870_splice | Splice Site (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100141698; called by muse, mutect2, varscan2
- RSPRY1 | c.1302G>C p.L434F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101070977; called by muse, varscan2
- RSRC1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99905894; called by muse, mutect2, varscan2
- RTN2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV99838857; called by muse, mutect2, varscan2
- RTTN | c.5512C>G p.L1838V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99731909; called by muse, mutect2, varscan2
- SBNO1 | c.811C>G p.P271A (on ENST00000420886; = p.P270A on NM_018183.5) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99928988; called by muse, mutect2, varscan2
- SCAF8 | c.2716C>G p.Q906E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.344); catalogued as COSV100914034; called by muse, mutect2, varscan2
- SCN8A | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100633641; called by muse, varscan2
- SERPINB2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as rs1462664086, COSV100208330; called by muse, mutect2, varscan2
- SERTAD2 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100512157; called by muse, mutect2, varscan2
- SGMS1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62371122; called by muse, mutect2, varscan2
- SHPK | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV99251178; called by muse, mutect2
- SLC12A5 | c.2569G>A p.D857N (on ENST00000454036 / NM_001134771.2; = p.D834N on NM_020708.5) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV99715751; called by muse, mutect2, varscan2
- SLC25A14 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV99502376; called by muse, mutect2, varscan2
- SMPD2 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs914698841, COSV57805240; called by muse, mutect2, varscan2
- SMPDL3B | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV100874569; called by muse, mutect2, varscan2
- SPANXN4 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100980965; called by muse, mutect2, varscan2
- SPIB | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.905); catalogued as rs1261540965, COSV99569896; called by muse, mutect2
- SSB | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs201142063; called by muse, mutect2, varscan2
- SSH2 | c.344G>T p.R115I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV99281825; called by muse, mutect2, varscan2
- SSRP1 | c.1368G>A p.M456I | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV99554860; called by muse, mutect2
- SSU72 | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV52218663, COSV99357276; called by muse, mutect2, varscan2
- SYAP1 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.024); catalogued as COSV101204930; called by muse, mutect2, varscan2
- SYNE2 | c.2341G>C p.D781H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100647366; called by muse, mutect2, varscan2
- SYT5 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV62831233; called by muse, mutect2, varscan2
- SYVN1 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.428); catalogued as COSV99589050; called by muse, mutect2, varscan2
- TACC2 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100552085; called by muse, mutect2, varscan2
- TAGAP | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100487364; called by muse, mutect2, varscan2
- TAS1R2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs553107029, COSV64745756; called by muse, mutect2, varscan2
- TASOR2 | c.5473G>T p.E1825* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100050313; called by muse, mutect2, varscan2
- TCTN1 | c.1283G>A p.R428Q (on ENST00000551590 / NM_001173975.3; = p.R414Q on NM_024549.6) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369266915; called by muse, mutect2, varscan2
- TENM1 | c.7026T>A p.Y2342* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100949708; called by muse, mutect2, varscan2
- THAP12 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV99473244; called by muse, mutect2
- TLR2 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs377645847, COSV52604922; called by muse, mutect2, varscan2
- TMPRSS5 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100244600; called by muse, mutect2, varscan2
- TRIM37 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs148095355; called by muse, mutect2, varscan2
- TRPM3 | c.3784G>A p.D1262N (on ENST00000357533 / NM_001366142.2; = p.D1117N on NM_020952.6) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62580811; called by muse, mutect2, varscan2
- TRUB2 | c.671-1G>A p.X224_splice | Splice Site (SNP) | VAF 25/33 reads (76%) | catalogued as COSV100867841; called by muse, mutect2, varscan2
- TTK | c.2131-1G>C p.X711_splice | Splice Site (SNP) | VAF 22/69 reads (32%) | catalogued as COSV57886385; called by muse, mutect2, varscan2
- TTK | c.2515G>A p.G839S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs764389041, COSV100036182; called by muse, mutect2, varscan2
- TTLL5 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV54033337; called by muse, varscan2
- TTN | c.89692G>A p.V29898M (on ENST00000591111; = p.V22474M on NM_003319.4) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | PolyPhen possibly damaging (0.528); catalogued as rs1403013054, COSV100605075; called by muse, mutect2, varscan2
- TTN | c.63834G>C p.K21278N (on ENST00000591111; = p.K13854N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | PolyPhen possibly damaging (0.647); catalogued as COSV60015858, COSV60420163; called by muse, mutect2, varscan2
- TTYH1 | c.1211G>C p.G404A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); catalogued as rs1384518642, COSV100001933, COSV56614945; called by muse, mutect2, varscan2
- TWNK | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747714427, COSV52967360; called by muse, mutect2, varscan2
- UNC13C | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as rs766948122, COSV52848821, COSV99515073; called by muse, mutect2, varscan2
- VWF | c.7551C>T p.V2517= | Splice Region (SNP) | VAF 19/53 reads (36%) | catalogued as rs145955543; called by muse, mutect2, varscan2
- WAC | c.1699C>T p.L567F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs12360326, COSV100610969; called by muse, mutect2, varscan2
- WAC | c.1751C>G p.S584* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100610970; called by muse, mutect2, varscan2
- WDR61 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.498); catalogued as COSV99144550; called by muse, mutect2, varscan2
- XKR8 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100871925; called by muse, mutect2, varscan2
- XYLT2 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.324); catalogued as rs1270666079, COSV99190850; called by muse, mutect2, varscan2
- ZEB1 | c.3157G>C p.E1053Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.092); catalogued as COSV100314119; called by muse, mutect2, varscan2
- ZNF462 | c.6853G>A p.E2285K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV99471414; called by muse, mutect2, varscan2
- ZNF571 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100143690; called by muse, mutect2, varscan2
- ZNF71 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV100045791; called by muse, mutect2, varscan2
- ZNF98 | c.1714A>G p.K572E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV100757400; called by muse, mutect2, varscan2
- CREBBP | c.5430del p.K1811Rfs*62 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel
- GPR179 | c.6814C>T p.P2272S (on ENST00000621958; = p.P2271S on NM_001004334.4) | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- H1-1 | c.262_265dup p.S89Kfs*44 | Frame Shift Ins (INS) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- IGLC3 | c.131C>A p.A44E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- RARG | c.199_200del p.S67Hfs*28 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by pindel, varscan2
- TRBV24-1 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 102/124 reads (82%) | SIFT tolerated (0.18); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF268 | c.628_629del p.L210Efs*7 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- ZNF532 | c.3391_3392del p.E1131Nfs*6 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- ZNF605 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZNF84 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 136/386 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ABCB8 | c.1461C>T p.F487= (on ENST00000297504 / NM_001282291.2; = p.F470= on NM_007188.5) | Silent (SNP) | VAF 44/59 reads (75%) | catalogued as COSV52512845; called by muse, mutect2, varscan2
- ACOT7 | c.633C>T p.I211= (on ENST00000377855 / NM_181864.3; = p.I201= on NM_007274.4) | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs762473178, COSV100830182; called by muse, mutect2, varscan2
- ADAMTS4 | c.1842C>T p.A614= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV100917730; called by muse, mutect2, varscan2
- AGO1 | c.447G>A p.Q149= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100940805; called by mutect2, varscan2
- AHNAK | c.8391C>G p.V2797= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV99946814; called by muse, mutect2, varscan2
- AIFM2 | c.111C>T p.F37= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV100325659, COSV100325672; called by muse, mutect2, varscan2
- AP1M2 | c.759C>T p.I253= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV99140793; called by muse, mutect2, varscan2
- AP2B1 | c.909G>C p.L303= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99251092; called by muse, mutect2, varscan2
- ARHGEF18 | c.2814G>A p.V938= (on ENST00000359920 / NM_001130955.2; = p.V834= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs758770572, COSV100149358; called by muse, mutect2, varscan2
- ATP8B3 | c.1306C>T p.L436= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100034303, COSV100034539; called by muse, mutect2, varscan2
- BSPRY | c.756G>A p.L252= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV53058070; called by muse, mutect2, varscan2
- BTNL8 | c.297G>C p.L99= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99180451; called by muse, mutect2, varscan2
- BTNL8 | c.918G>C p.L306= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99180452; called by muse, mutect2
- C8orf37 | c.279C>G p.V93= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV99713111; called by muse, mutect2, varscan2
- CAND1 | c.2284C>T p.L762= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV101607311; called by muse, mutect2, varscan2
- CAPN2 | c.135C>T p.L45= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV99688795; called by muse, mutect2, varscan2
- CCDC73 | c.2574C>T p.F858= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs201555986; called by muse, mutect2, varscan2
- CDK12 | c.1737C>T p.S579= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs775559482, COSV101420411; called by muse, mutect2, varscan2
- CKM | c.588G>A p.K196= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- CNGB1 | c.1716G>A p.V572= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV99202309; called by muse, mutect2, varscan2
- CYP27A1 | c.732C>T p.I244= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs1224145759, COSV99298446; called by muse, mutect2, varscan2
- DEK | c.534G>A p.R178= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99788830; called by muse, mutect2, varscan2
- DICER1 | c.255C>T p.I85= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as CM151411, COSV100601977, COSV58617794; called by muse, mutect2, varscan2
- DSC1 | c.33C>A p.I11= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99937493; called by muse, mutect2, varscan2
- E4F1 | c.621C>G p.L207= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100065579, COSV57040810; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1602C>G p.L534= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV100668547; called by muse, mutect2, varscan2
- EHBP1 | c.1602G>C p.L534= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs768004760, COSV99860575; called by muse, mutect2, varscan2
- FGF5 | c.78C>T p.L26= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV100427839; called by muse, mutect2, varscan2
- FRMD4A | c.2154C>T p.L718= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100661654; called by muse, mutect2, varscan2
- GJA10 | c.327G>A p.R109= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1329815734, COSV65354950; called by muse, mutect2, varscan2
- GNPNAT1 | c.327C>T p.F109= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV53591577; called by muse, mutect2, varscan2
- GOLGB1 | c.4653C>T p.L1551= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV61465943; called by muse, mutect2, varscan2
- GPATCH8 | c.3759G>A p.L1253= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100132574; called by muse, mutect2, varscan2
- H2AC4 | c.132C>T p.V44= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99451442; called by muse, mutect2, varscan2
- HAS3 | c.612C>G p.L204= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs768007153, COSV54708195, COSV99544432; called by muse, mutect2, varscan2
- HS6ST2 | c.483C>T p.L161= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV100897148; called by muse, mutect2, varscan2
- IGF1 | c.567C>T p.C189= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100190775; called by muse, mutect2, varscan2
- IGHG2 | c.138G>A p.L46= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- IGHG4 | c.138G>A p.L46= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- IL4R | c.1479C>T p.G493= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99404929; called by muse, mutect2, varscan2
- ITGB2 | c.1611C>T p.V537= (on ENST00000302347; = p.V513= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100185765; called by muse, mutect2, varscan2
- ITPR1 | c.6954C>A p.L2318= (on ENST00000354582; = p.L2263= on NM_002222.7) | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100230661; called by muse, mutect2, varscan2
- ITPR2 | c.1437C>A p.L479= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV101189933, COSV67266366; called by muse, mutect2, varscan2
- IZUMO1 | c.912G>A p.L304= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV55804335; called by muse, mutect2, varscan2
- KAT14 | c.1131C>T p.V377= | Silent (SNP) | VAF 49/77 reads (64%) | catalogued as COSV100890058; called by muse, mutect2, varscan2
- KAT14 | c.1479C>G p.R493= | Silent (SNP) | VAF 57/91 reads (63%) | catalogued as COSV100890060; called by muse, varscan2
- KHDRBS1 | c.342C>T p.L114= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100306153; called by muse, varscan2
- KRT13 | c.1174C>T p.L392= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99877312; called by muse, mutect2, varscan2
- LPXN | c.24G>A p.L8= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV101223002; called by muse, mutect2, varscan2
- LRRIQ4 | c.228C>T p.L76= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100540183, COSV61619665; called by muse, mutect2, varscan2
- MAGEH1 | c.264G>A p.K88= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV100746796, COSV61678734; called by muse, mutect2, varscan2
- MC3R | c.618C>G p.L206= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV99710537; called by muse, mutect2, varscan2
- MFSD6L | c.582G>A p.L194= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1292928202, COSV61001459; called by muse, mutect2, varscan2
- MICALL1 | c.2352G>A p.L784= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99317172; called by muse, mutect2, varscan2
- MLH3 | c.2184G>A p.R728= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99470063; called by muse, mutect2, varscan2
- MRGPRF | c.345C>T p.I115= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as rs1388557302, COSV100307819; called by muse, mutect2, varscan2
- MRPL35 | c.9C>G p.A3= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs376000590, COSV99607165; called by muse, mutect2, varscan2
- MYO7B | c.3036C>A p.V1012= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV101268056; called by muse, mutect2, varscan2
- NSD2 | c.3909C>T p.F1303= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs767126550, COSV100373093; called by muse, mutect2, varscan2
- OR13F1 | c.915G>T p.L305= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100594727; called by muse, mutect2
- OR14A16 | c.591C>G p.L197= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100713747; called by muse, mutect2, varscan2
- PDGFRL | c.828C>T p.I276= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV52415618; called by muse, mutect2, varscan2
- PHACTR4 | c.1494C>T p.V498= (on ENST00000373839 / NM_001350159.2; = p.V508= on NM_023923.4) | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100868427; called by muse, mutect2, varscan2
- PIGM | c.1050C>T p.V350= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as rs1247493860, COSV100928020; called by muse, mutect2, varscan2
- PLPP4 | c.288C>T p.V96= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100956285; called by muse, mutect2, varscan2
- POLE | c.1770G>A p.V590= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1060504050, COSV100266024; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKDC | c.4255C>T p.L1419= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100039793; called by muse, mutect2, varscan2
- PTPRT | c.360G>A p.L120= | Silent (SNP) | VAF 60/98 reads (61%) | catalogued as COSV100626543; called by muse, mutect2, varscan2
- RALGAPA2 | c.3579G>A p.L1193= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99173377; called by muse, mutect2, varscan2
- RCC2 | c.1530G>A p.K510= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100965134, COSV64906029, COSV64906344; called by muse, mutect2, varscan2
- RNF144B | c.801C>T p.I267= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99464474; called by muse, mutect2, varscan2
- SCARA3 | c.675C>T p.F225= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100106662; called by muse, mutect2, varscan2
- SFSWAP | c.2523G>A p.R841= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99905975; called by muse, varscan2
- SLC36A3 | c.702C>T p.I234= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100077507; called by muse, mutect2, varscan2
- SLC7A4 | c.165C>T p.L55= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100298646, COSV60384838; called by muse, mutect2, varscan2
- SYCP1 | c.2274T>A p.A758= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs200544411, COSV101050879; called by muse, mutect2, varscan2
- TAS2R41 | c.855C>T p.F285= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs750163018, COSV68765049; called by muse, mutect2, varscan2
- TELO2 | c.2100C>T p.F700= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99248202; called by muse, mutect2, varscan2
- TMEM132B | c.1230G>A p.E410= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV54771187; called by muse, mutect2, varscan2
- TRAM1L1 | c.144C>T p.I48= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100162126; called by muse, mutect2, varscan2
- TRPM6 | c.3414C>T p.L1138= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100666152, COSV62510210; called by muse, mutect2, varscan2
- TTF2 | c.3336C>T p.V1112= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs776200480, COSV101037393; called by muse, mutect2, varscan2
- TTLL5 | c.2724C>G p.L908= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100089772; called by muse, varscan2
- UBASH3A | c.393G>C p.L131= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV52317636, COSV99369472; called by muse, mutect2, varscan2
- UBLCP1 | c.735G>A p.K245= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV99707320; called by muse, mutect2, varscan2
- UBXN7 | c.1365C>T p.L455= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs781576265, COSV99581126; called by muse, mutect2, varscan2
- UGT2A1 | c.993G>A p.Q331= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs1007072892, COSV99684150; called by muse, mutect2, varscan2
- UNC13C | c.27G>A p.L9= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99515067; called by muse, varscan2
- UPK2 | c.477C>T p.I159= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV104382351, COSV99875004; called by muse, mutect2, varscan2
- USP51 | c.738C>G p.L246= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV101540655; called by muse, mutect2, varscan2
- USP6 | c.2877G>A p.Q959= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100003655; called by muse, mutect2, varscan2
- WNT1 | c.171C>T p.L57= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs770381881, COSV99525270; called by muse, mutect2, varscan2
- GSG1 | c.481+58G>A | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as rs773172378, COSV60969838, COSV60970664; called by muse, mutect2, varscan2
- HERC2P3 | n.742G>A | RNA (SNP) | VAF 53/242 reads (22%) | catalogued as rs540674068; called by muse, mutect2, varscan2
- IGLL5 | chr22:22901105 C>A | 3'Flank (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- SREK1 | chr5:66144421 C>T | 5'Flank (SNP) | VAF 74/187 reads (40%) | catalogued as rs1561488302, COSV100485644; called by muse, mutect2, varscan2
